Somatic mutation profile of tumor specimen 0DU3KT from CCDI case PBCKPF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 12.0 years (4,394 days).
Specimen 0DU3KT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3b053ab-4b1a-4bec-9e6c-a28b1f264493.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU3MU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9bbc0397-3f29-4cfb-9123-68e016284f4c

The open-access MAF lists 30 somatic variants for this specimen: 21 protein-altering or splice-affecting, 2 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Intron 4, 3'UTR 3, Silent 2, Frame Shift Del 1, Frame Shift Ins 1, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 1046/2420 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913399, COSV62687911, COSV62687931, COSV62721471; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GJB4 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 458/1151 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1403929835, COSV58355605; called by muse, mutect2, varscan2
- GRIN2C | c.1711G>A p.V571I | Missense Mutation (SNP) | VAF 159/1918 reads (8%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.889); catalogued as rs749558742, COSV53111524, COSV53114024; called by muse, mutect2
- KDM5C | c.1546G>C p.E516Q | Missense Mutation (SNP) | VAF 339/2980 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64764457, COSV64765743; called by muse, mutect2, varscan2
- MUC12 | c.8076del p.T2693Pfs*93 (on ENST00000379442; = p.T2550Pfs*93 on NM_001164462.1) | Frame Shift Del (DEL) | VAF 8/55 reads (15%) | catalogued as rs1554342786; called by mutect2, pindel, varscan2
- OR5F1 | c.93dup p.L32Sfs*34 | Frame Shift Ins (INS) | VAF 411/2111 reads (19%) | catalogued as rs752982370; called by mutect2, pindel, varscan2
- SLC35B2 | c.1231G>A p.A411T | Missense Mutation (SNP) | VAF 509/1350 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs61740055; called by muse, mutect2, varscan2
- TRIM51 | c.176C>T p.T59M | Missense Mutation (SNP) | VAF 685/3535 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as rs1249359165, COSV55266215; called by muse, mutect2, varscan2
- TTLL12 | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 211/1005 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as COSV53354428; called by muse, mutect2, varscan2
- VASN | c.945G>C p.E315D | Missense Mutation (SNP) | VAF 56/1240 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs752531352; called by muse, mutect2
- ZBTB49 | c.2170G>A p.G724S | Missense Mutation (SNP) | VAF 98/1246 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs145779018, COSV61925136; called by muse, mutect2
- DDX3X | c.830T>C p.L277S (on ENST00000399959; = p.L278S on NM_001356.5) | Missense Mutation (SNP) | VAF 92/2865 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GPRASP1 | c.2329G>A p.D777N | Missense Mutation (SNP) | VAF 266/2457 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- HEATR3 | c.394A>T p.K132* | Nonsense Mutation (SNP) | VAF 104/3162 reads (3%) | called by muse, mutect2
- IVL | c.917C>T p.P306L | Missense Mutation (SNP) | VAF 1448/2225 reads (65%) | SIFT tolerated (0.32); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- JADE3 | c.947A>C p.K316T | Missense Mutation (SNP) | VAF 441/1994 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- NCLN | c.1391G>C p.R464P | Missense Mutation (SNP) | VAF 120/1503 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); called by muse, mutect2
- RBBP7 | c.75_77del p.K25del | In Frame Del (DEL) | VAF 404/1986 reads (20%) | called by pindel, varscan2
- TNS2 | c.137G>C p.C46S (on ENST00000314250 / NM_170754.4; = p.C56S on NM_015319.2) | Missense Mutation (SNP) | VAF 325/2472 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TSPOAP1 | c.2764C>T p.P922S | Missense Mutation (SNP) | VAF 291/1283 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTN | c.23734G>A p.E7912K (on ENST00000591111; = p.E6985K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 491/2180 reads (23%) | PolyPhen benign (0.069); called by muse, mutect2, varscan2
- DUSP7 | c.264C>T p.I88= | Silent (SNP) | VAF 642/1510 reads (43%) | catalogued as COSV99623490; called by muse, mutect2, varscan2
- TAF1 | c.1626A>G p.K542= (on ENST00000373790 / NM_138923.4; = p.K563= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 523/1597 reads (33%) | called by muse, mutect2, varscan2
- KLRC1 | c.283+24A>G | Intron (SNP) | VAF 227/1061 reads (21%) | catalogued as rs774246866; called by muse, mutect2, varscan2
- M6PR | c.-1-66C>T | Intron (SNP) | VAF 56/321 reads (17%) | catalogued as rs952533340; called by muse, mutect2, varscan2
- MEST | c.261+69C>G | Intron (SNP) | VAF 136/612 reads (22%) | called by muse, mutect2, varscan2
- PARPBP | c.*935A>T | 3'UTR (SNP) | VAF 33/1168 reads (3%) | called by muse, mutect2
- PGAM5 | c.*75C>T | 3'UTR (SNP) | VAF 120/1137 reads (11%) | catalogued as rs963886162; called by muse, mutect2, varscan2
- PHB2 | c.607+21G>A | Intron (SNP) | VAF 122/1222 reads (10%) | called by muse, mutect2
- ZNF33B | c.*53T>C | 3'UTR (SNP) | VAF 40/1482 reads (3%) | called by muse, mutect2
